CPTAC case C3L-01884 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae481eb3-8f9d-42cd-a431-6f289c8a8779

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Dead; Days to death: 1,653 days (4.5 years); Year of death: 2021; Cause of death: Not Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 74.8 years (27,320 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,653 days (4.5 years); Progression or recurrence: no; Days to last follow up: 1,483 days (4.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm (a second GDC size field records 4.7 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 17; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 684 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,380 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,380 days (3.8 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 173 days.
- Days to follow up: 1,483 days (4.1 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 362, day 1,082.

Other clinical attributes
- Weight: 82 kg; Height: 170.18 cm; BMI: 28.31; DLCO (% of predicted): 55; FEV1/FVC after bronchodilator (%): 41; FEV1/FVC before bronchodilator (%): 43; FEV1 after bronchodilator (% of reference): 63; FEV1 before bronchodilator (% of reference): 67.

Exposures
- Tobacco smoking status: Current Smoker; Cigarettes per day: 30; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 308 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01884-22: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 7.
- Sample C3L-01884-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 583 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01884-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
